Surgical pathology report (de-identified scan), TCGA case TCGA-FG-5965, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western, specimen TCGA-FG-5965-02B (Recurrent Tumor).

SURGICAL PATHOLOGY REPORT

Race: CAUCASIAN
DOB/Sex: / F

FINAL DIAGNOSIS

A., B. RIGHT OCCIPITAL AND TEMPORAL NEOPLASM, REMOVAL:
-- GLIOBLASTOMA MULTIFORME (WHO GRADE IV) DEMONSTRATING FOCAL OLIGODENDROGLIOMA DIFFERENTIATION.

Note: Microvascular proliferation is identified. Focal coagulative necrosis without pseudo-palisading is also present.

C. SUPERFICIAL CORTEX, BIOPSY:
-- INFILTRATING GLIOMA.

Electronically Signed Out By

By the signature on this report, the individual or group listed as making the Final Interpretation/Diagnosis certifies that they have reviewed this case.

Intraoperative Consultation:

A. Frozen section, microscopic: Malignant glioma with focal necrosis.

Clinical History:

brain tumor

Specimens Submitted As:

A: RIGHT OCCIPITAL NEOPLASM
B: RIGHT TEMPORAL TUMOR
C: SUPERFICIAL CORTEX

ICD-0-3
glioblastoma, multiforme 9440/3
Site: brain, frontal lobe C71.1

hw 10/23/12

Gross Description:

A. Received fresh for intraoperative consultation, labeled with the patient's name, Hospital number, and "right occipital neoplasm", is a 1 x 1 x 0.3 cm aggregate of white-tan soft tissue fragments. A portion is submitted for frozen section. The remainder is submitted entirely in two cassettes.

B: Received fresh, post fixed in formalin, labeled with the patient's name and number, are multiple pink-tan to focally red-brown irregular soft tissue fragments measuring 3.6 x 2.8 x 1.5 cm in aggregate. On section, the fragments are light tan to tan-gray. Submitted entirely in three cassettes.

C: Received fresh, post fixed in formalin, labeled with patient's name, number, and "superficial cortex", is one pink-tan irregular soft tissue fragment measuring 0.9 x 0.5 x 0.4 cm. Submitted in toto in one cassette.

Summary of cassettes

A 1FS frozen section
2 remainder of specimen

(recurrence 2 of 2)
GBM recurr

ICDAA Discrepancy		
For Malignancy History		

hw 10/23/12

Source: NCI Genomic Data Commons file b2ff7d2d-6428-41f6-a7fa-c4a5471d81e8 (TCGA-FG-5965.DD2349DD-E128-4C2D-962B-F8644121FB16.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).